Somatic mutation profile of tumor specimen TCGA-ET-A39L-01A (aliquot TCGA-ET-A39L-01A-12D-A19J-08) from TCGA case TCGA-ET-A39L, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 20.9 years (7,636 days).
Specimen TCGA-ET-A39L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bb9f407-6b3f-4fc3-ba5c-f8d86fe7b997.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39L-10A (Blood Derived Normal), aliquot TCGA-ET-A39L-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e41a2670-a845-4db3-8489-f65bce154e8e

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAT | c.3514T>C p.C1172R | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1474991170, COSV53721693; called by muse, mutect2
- TNC | c.6601G>A p.A2201T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs868055775, COSV60790015; called by muse, mutect2
- ZC3H11A | c.1107C>T p.A369= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV59750154; called by muse, mutect2
- ASIC4 | c.-23C>T | 5'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
